Surgical pathology report (de-identified scan), TCGA case TCGA-FW-A5DX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site International Genomics Consortium, specimen TCGA-FW-A5DX-01A (Primary Tumor).

[page 1 of 3]
Patient Results

M

Final

Path Report

SURGICAL PATHOLOGY REPORT

ACCESSION NO. : [REDACTED]

Final Diagnosis(es):

(A) Left anterior chest wall melanoma, biopsy:

1) Residual melanoma.

2) All margins negative.

3) Previous biopsy site change.

(B) Left axillary lymph contents:

Four of eleven lymph nodes positive for melanoma with extracapsular invasion (45 mm largest positive node).

(C) Level 3 left axillary lymph node, excision: Two lymph nodes negative for melanoma.

The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Left anterior chest wall melanoma

B: Left axillary LN contents

C: Level 3 left axillary LN

Clinical History:

Left anterior chest wall melanoma. [REDACTED]

Gross Description:

(A) (left anterior chest wall melanoma) Received in formalin is an oriented elliptical excision of red-gray smooth skin that is 9.6 x 5.3 cm up to 2.5 cm deep. There is a suture placed at one pointed end designated lateral hereafter 12:00. There is, one the central epidermis a retracted gray-white scar that is 1.8 cm long x 0.4 cm wide with brown nodularity upon one end measuring 0.7 x 0.4 cm. The brown nodularity is within 1.9 cm of the 2:30 margin. The 12:00-3:00 margin is inked green, the 3:00-6:00 margin blue, the 6:00-9:00 margin orange, the 9:00-12:00 margin red and the deep margin is inked black.

Circumferential en face margins are taken and submitted sequentially in clockwise fashion beginning at 12:00 in cassettes A1-A9. The remaining specimen is serially sectioned perpendicularly to its long axis and the entire scar site is submitted and surrounding deep tissue to the deep margin with:

10-11 full-thickness step section divided,

A10 - representing the 9:00 half and

A11 - the 3:00 half

A12-A13 - full-thickness step sections divided

A14-A15 - full-thickness step sections divided

A16-A17 - full-thickness step sections divided

A18-A19 - full-thickness step sections divided

ICD-O-3

Melanoma, NOS 8720/3

Site: Skin, (L) Chest wall
C44.5

gn 1/2/2013

[page 2 of 3]
Patient Results

M

A20 - full-thickness step section divided

A21 - full-thickness step section divided

(B) (left axillary lymph node contents) Received fresh for Tumor Bank sampling and subsequently placed in formalin is a 380 gm 13.8 x 12.5 x 7.0 cm portion of tan-yellow lobulated fibroadipose tissue. Dissection and palpation yield 15 dark gray to pale tan-pink rubbery lymph nodes ranging in size from 0.3 to 4.5 cm, some focally replaced by fat, one lymph node is submitted sectioned entirely in B1 and B2. One lymph node is sectioned, submitted entirely in B3. One lymph node is serially sectioned and submitted entirely in B4. One lymph node serially sectioned and submitted entirely in B5. One lymph node serially sectioned and submitted entirely in B6. Four lymph nodes are submitted intact in cassette B7. Two lymph nodes are submitted intact in cassette B8. One lymph node is serially sectioned and submitted entirely in cassettes B9-B11. One lymph node is serially sectioned submitted entirely in cassettes B12-B13. A representative section of one of the larger lymph nodes is submitted in cassette B14 and a representative section of the largest lymph node previously sampled for Tumor Bank is submitted in cassette B15.

(C) (level three left axillary lymph node) Received in formalin are two tan-pink rubbery lymph nodes that are 0.7 and 1.5 cm in greatest dimension. The smaller is submitted entirely intact in C1, the larger is trisected submitted entirely in cassette C2.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at The

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are

[page 3 of 3]
Patient Results

M

scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Criteria	W 12/21/12	Yes	No
Biopsy Discrepancy			✓
Pathologic Malignancy History			✓
GL/SL/Non-Hodgkin's Primary Malignancy			✓
Reviewed (initials)	12/21/12		

Printed from: Default

End of Report

Page: 3 of 3

Source: NCI Genomic Data Commons file a95fda82-a86d-4b9c-baab-a368adb8ff19 (TCGA-FW-A5DX.D34CA06D-F2E8-47A5-85D1-CA627AE0BE9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).